Somatic mutation profile of tumor specimen BA2685D (aliquot aq-BA2685D) from BEATAML1.0 case 2266, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,578 days).
Specimen BA2685D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d724cf77-e0c2-4cf4-91b2-bf40af63357d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2958D (Solid Tissue Normal), aliquot aq-BA2958D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e574ead-a725-43e5-85a7-fbe4a9057aeb

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Splice Site 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 152/548 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- BCOR | c.2514dup p.K839Qfs*5 | Frame Shift Ins (INS) | VAF 59/104 reads (57%) | catalogued as rs1394942244; called by mutect2, pindel, varscan2
- CRHR2 | c.697T>C p.C233R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as rs1275337507; called by muse, mutect2, varscan2
- KRTAP11-1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as rs199724044, COSV60095174; called by muse, mutect2, varscan2
- LGI1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 142/572 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs201376381, COSV65057719; ClinVar: uncertain significance; called by muse, varscan2
- TAFA4 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as rs35815841; called by muse, mutect2, varscan2
- TBRG4 | c.1794+1G>A p.X598_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as rs746533037, COSV99345209; called by muse, varscan2
- ZNF326 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1032326684; called by muse, mutect2, varscan2
- ANKRD63 | c.265A>C p.S89R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.28); called by muse, mutect2, varscan2
- CRELD2 | c.414C>A p.L138= | Splice Region (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- MAP7D1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MPHOSPH9 | c.3405G>C p.M1135I | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RIPK1 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RNH1 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- STRN | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TCF19 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UTP14C | c.885C>A p.S295R | Missense Mutation (SNP) | VAF 223/578 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKRD30BL | c.252T>C p.H84= | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, varscan2
- LNPEP | c.1011C>T p.V337= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs142457895; called by muse, mutect2, varscan2
- MRPL38 | c.489C>T p.H163= | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as rs377432588; called by muse, mutect2, varscan2
- SERPINB13 | chr18:63604012 A>G | 3'Flank (SNP) | VAF 51/114 reads (45%) | called by muse, mutect2, varscan2
